MMRF case MMRF_1193 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/85ac98f4-1e36-4340-95ab-24132db58d43

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 1,564 days (4.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.0 years (23,023 days); ISS stage: I; Days to last known disease status: 1,564 days (4.3 years); Days to last follow up: 1,564 days (4.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 144 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 596 days (1.6 years); Days to treatment end: 682 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 896 days (2.5 years); Days to treatment end: 1,321 days (3.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,381 days (3.8 years); Days to treatment end: 1,437 days (3.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,381 days (3.8 years); Days to treatment end: 1,437 days (3.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,564.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 5 g/dL; Immunoglobulin G 72.2 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 4.33 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 11.5 g/dL; Glucose 5.01 mmol/L.
- Day 102 (ECOG 1): M Protein 0.2 g/dL; Immunoglobulin G 4.88 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 7.29 ×10⁹/L; Absolute Neutrophil 6.55 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Total Protein 6.9 g/dL; Glucose 9.46 mmol/L.
- Day 172 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 4.96 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.51 ×10⁹/L; Absolute Neutrophil 2.47 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Total Protein 6.7 g/dL; Glucose 6.11 mmol/L.
- Day 283 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 6.76 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.69 ×10⁹/L; Absolute Neutrophil 2.67 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Total Protein 7 g/dL; Glucose 4.84 mmol/L.
- Day 351 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 7.46 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.28 ×10⁹/L; Absolute Neutrophil 3.17 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.58 mmol/L; Total Protein 7.1 g/dL; Glucose 7.21 mmol/L.
- Day 466 (ECOG 1): M Protein 0.2 g/dL; Immunoglobulin G 8.6 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.6 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.15 ×10⁹/L; Absolute Neutrophil 2.89 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.5 mmol/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.
- Day 541 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.882 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.88 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.59 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.05 ×10⁹/L; Absolute Neutrophil 4.25 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.55 mmol/L; Total Protein 7.1 g/dL; Glucose 4.46 mmol/L.
- Day 630 (ECOG 1): M Protein 0.3 g/dL; Immunoglobulin G 6.25 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.53 ×10⁹/L; Absolute Neutrophil 5.89 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Total Protein 6.14 g/dL; Glucose 8.91 mmol/L.
- Day 722: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.715 mg/dL; Immunoglobulin G 5.3 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.42 ×10⁹/L; Absolute Neutrophil 2.18 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.58 mmol/L; Albumin 48 g/L; Total Protein 7 g/dL; Glucose 5.89 mmol/L.
- Day 813 (ECOG 0): M Protein 0.4 g/dL; Immunoglobulin G 9.09 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.58 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.16 ×10⁹/L; Absolute Neutrophil 2.23 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.58 mmol/L; Albumin 47 g/L; Total Protein 7 g/dL; Glucose 5.17 mmol/L.
- Day 889 (ECOG 0): M Protein 0.7 g/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.42 ×10⁹/L; Absolute Neutrophil 3.51 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.63 mmol/L; Total Protein 7.8 g/dL; Glucose 8.2 mmol/L.
- Day 982: M Protein 0.3 g/dL; Immunoglobulin G 6.35 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.58 ×10⁹/L; Absolute Neutrophil 2.41 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 5.83 mmol/L.
- Day 1,066 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 9.39 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 1.69 µg/mL; Hemoglobin 8.49 mmol/L; Leukocytes 3.39 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 1,178: M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.38 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.74 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 2.54 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 4.9 mmol/L.
- Day 1,284: M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 30.3 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.79 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 2.94 ×10⁹/L; Absolute Neutrophil 1.48 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.5 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 7.48 mmol/L.
- Day 1,368 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 263 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 4.4 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 5.21 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 44.5 g/L; Total Protein 7.4 g/dL; Glucose 5.12 mmol/L.
- Day 1,466 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 190 mg/dL; Immunoglobulin G 3.84 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 21 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.48 ×10⁹/L; Platelets 38 ×10⁹/L; Creatinine 424 µmol/L; Blood Urea Nitrogen 17.1 mmol/L; Calcium 2.5 mmol/L; Albumin 39.8 g/L; Total Protein 6.8 g/dL; Glucose 7.32 mmol/L.

Other clinical attributes
- Day -13: Weight: 68 kg; Height: 157 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Multiple Myeloma.
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship primary diagnosis: Kidney Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (3 samples)
- Sample MMRF_1193_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 630 days (1.7 years).
- Sample MMRF_1193_3_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 630 days (1.7 years).
- Sample MMRF_1193_5_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 889 days (2.4 years).
